Surgical pathology report (de-identified scan), TCGA case TCGA-06-5416, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-5416-01A (Primary Tumor).

[page 1 of 5]
TCGA-06-5416

CLINICAL HISTORY

[REDACTED] had a brain CT on [REDACTED] that was negative. Currently has a large inferior, posterior left temporal tumor with zone of necrosis, marked solid enhancement, and prominent edema and mass effect.

OPERATIVE DIAGNOSES

Left temporal mass

Operation/Specimen: A: Brain, left temporal tumor, biopsy
B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, left temporal, excisional biopsy and excision:

1. Glioblastoma.
2. MIB-1 proliferation index: Up to 50%.
- See Microscopy Description and Comment.

COMMENT

Sections demonstrate a highly cellular glial neoplasm with marked cytologic atypia, brisk mitotic activity with very high MIB-1 proliferation index of up to 50%, and somewhat inconspicuous microvascular proliferation. There is no tumor necrosis.

In the material examined the neoplasm is a glioblastoma devoid of frank tumor necrosis. In the infiltrative areas of the neoplasm there is a suggestion of a possible oligodendroglial component.

Testing for 1p, 19q LOH will be performed and reported as an addendum.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED]

Date Reported: [REDACTED]

Interpretation

[page 2 of 5]
NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments
Test performed on

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected. See comment

Results-Comments
Test performed on

TEST DESCRIPTION: Testing performed on RNA extracted from [REDACTED] (B1) and [REDACTED]

RNA quality: [REDACTED] (B1) : Good
: [REDACTED] : Marginal

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III (EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

[page 3 of 5]
[REDACTED]

determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

Interpretation
There is a partial loss of chromosome arm 1p (telomeric region - D1S1612)

NEGATIVE: Allelic loss on chromosome arm 19q is NOT detected.

Informative loci are: D1S1612, D1S496, D19S219, PLA2G4C, D19S606 and D19S1182

Results-Comments

Testing performed on DNA extracted from tumor paraffin block [REDACTED] (B1) and [REDACTED] DNA extracted from a corresponding blood specimen was used as [REDACTED] control. The partial loss of chromosome 1p is better seen in sample [REDACTED] compared to [REDACTED] (B1)

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

[REDACTED]

PRE-OPERATIVE CONSULTATION

Brain, left temporal tumor, biopsy: High histological grade neoplasm, of neuroepithelial origin (R/O GBM, PNET other). [REDACTED] Touch preparation smears performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[page 4 of 5]
GROSS DESCRIPTION

A.
"Left temporal tumor," received fresh, two fragments, 0.5 cm in aggregate.
Semi firm, tannish white, glistening. In total, A1.

B.
Brain, excision biopsy:
CONTAINER LABEL: left temporal tumor
FIXATIVE: Formalin. NO. PIECES: 2 tan-pink, glistening, soft tissue
fragments. SIZE/VOL: 0.6 and 0.7 cm. CASSETTES: 1, [REDACTED] [REDACTED]

MICROSCOPIC DESCRIPTION

H SECTIONS IMMUNOHISTOCHEMISTRY:

Sections demonstrate a highly cellular neoplasm with marked cytologic atypia. The cells have sparse to abundant cytoplasm and highly pleomorphic, atypical nuclei. The GFAP immunohistochemical stain is strongly positive in the neoplastic cells, while NeuN is negative. There are numerous normal and atypical mitoses, up to 16 per 10 high power fields. The MIB-1 proliferation index is up to 45 - 50%, and the p53 protein is strongly expressed in 5 -10% of the neoplastic nuclei. There is some microvascular proliferation. There is no tumor necrosis.

The frozen section diagnosis is confirmed on the permanent sections

ICD-9(s):
191.9 191.9

Histo Data

Part A: Brain, left temporal tumor, biopsy
Taken: [REDACTED] Received: [REDACTED]
in/cnt Block Ordered Comment
x 1 1 [REDACTED]
TPS H/E x 1 1 [REDACTED]

Part B: Brain, excision biopsy
Taken: [REDACTED] Received: [REDACTED]
Stain/cnt Block Ordered Comment
EGFR VIII-slides x 1 1 [REDACTED]

[page 5 of 5]
mCAPP-DA x 1	1
H. x 1	1
MGMT-slides x 1	1
MIB1-DA x 1	1
NeuN x 1	1
P53D07 x 1	1

*** End of Report ***

Source: NCI Genomic Data Commons file e85eb775-f169-4a3a-b7d4-024c5a036856 (TCGA-06-5416.95607F05-091A-4F35-9A8B-446773C316F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).